TCGA case TCGA-18-3409 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Princess Margaret Hospital (Canada). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b09e872a-e837-49ec-8a27-84dcdcabf347

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 74 years; Vital status: Alive.

Diagnoses (4)
1. Basaloid squamous cell carcinoma (the primary disease): ICD-O-3 morphology code: 8083/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 74.3 years (27,154 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 3,747 days (10.3 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Basaloid squamous cell carcinoma: ICD-O-3 morphology code: 8083/3; Tissue or organ of origin: Lung, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 74.3 years (27,127 days); Days to diagnosis: -27 days; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Lung.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Skin of other and unspecified parts of face; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 80.6 years (29,445 days); Days to diagnosis: 2,291 days (6.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.

Follow-up (2 entries)
- Days to follow up: 2,417 days (6.6 years); Disease response: Tumor Free.
- Days to follow up: 3,747 days (10.3 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking quit year: 1974.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-18-3409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-18-3409-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25.
  Slide TCGA-18-3409-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20.
- Sample TCGA-18-3409-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-18-3409-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.4; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Basaloid Squamous Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper; Pulmonary function test indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; Tumor status: Tumor free; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 1, New neoplasm event types: New tumor event type: New Primary Tumor.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Biopsy with Histologic Confirmation.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Forehead; Other malignancy histological type: Basal Cell Carcinoma.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -3127.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Basaloid Squamous Cell.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Bilateral anterior thoracotomies with right upper lobectomy (and left upper lobectomy for synchronous tumour).

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy basal cell carcinoma of the forehead. No systemic chemotherapy or radiation. Prior malignancy basaloid squamous cell carcinoma of the anal canal treated with chemotherapy and radiation.
- Prior malignancy: Prior malignancy basal cell carcinoma of the forehead. No systemic chemotherapy or radiation. Prior malignancy basaloid squamous cell carcinoma of the anal canal treated with chemotherapy and radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,747 days; disease-specific survival: no event (censored), 3,747 days; disease-free interval: no event (censored), 3,747 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,291 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-18-3409-01): tumor purity 0.54, ploidy 3.57, whole-genome doublings 1 (call status: maf_call).
